MMRF case MMRF_1325 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7903893f-3929-4086-93ce-caab4a211027

Demographics
Sex at birth: female; Race: other; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.9 years (21,512 days); ISS stage: III; Days to last known disease status: 1,467 days (4.0 years); Days to last follow up: 1,467 days (4.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 39 days; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 148 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 99 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 5.8 µg/mL; Lactate Dehydrogenase 5.6 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.63 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 9.24 mmol/L.
- Day 88 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 30 mg/dL; Immunoglobulin G 5.79 g/L; Immunoglobulin A 2.55 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 8.25 mmol/L.
- Day 148 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 54.3 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 2.75 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 7.87 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 384 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 14.5 mmol/L.
- Day 245 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.49 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.58 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 10.1 mmol/L.
- Day 336 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.66 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 441 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.33 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 7.21 mmol/L.
- Day 532 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.69 mg/dL; Immunoglobulin G 1.17 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 10.1 mmol/L.
- Day 626 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.33 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 9.52 mmol/L.
- Day 707 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.74 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.99 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 11.2 mmol/L.
- Day 798 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.16 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 7.54 mmol/L.
- Day 897 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.57 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 9.52 mmol/L.
- Day 991 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.37 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 2.51 g/L; Immunoglobulin M 0.62 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 10.7 mmol/L.
- Day 1,082 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.79 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.62 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 8.31 mmol/L.
- Day 1,183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.23 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 8.75 mmol/L.
- Day 1,278 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 2.61 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 9.24 mmol/L.
- Day 1,376 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.28 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 3.21 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 12.6 mmol/L.
- Day 1,467 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.85 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 3.55 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 11.3 mmol/L.

Other clinical attributes
- Day -7: Weight: 134 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1325_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1325_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
